Somatic mutation profile of tumor specimen TCGA-FS-A1ZT-06A (aliquot TCGA-FS-A1ZT-06A-11D-A197-08) from TCGA case TCGA-FS-A1ZT, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.6 years (20,665 days).
Specimen TCGA-FS-A1ZT-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d88f869-3602-4c41-840c-b4ac61ac7511.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZT-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZT-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d906cd59-5313-474d-9367-a3ccfc25cc5c

The open-access MAF lists 199 somatic variants for this specimen: 134 protein-altering or splice-affecting, 57 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 57, Nonsense Mutation 12, RNA 3, Intron 2, Splice Site 1, 5'UTR 1, Frame Shift Ins 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL16 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 28/44 reads (64%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs768772097, COSV61266597; called by muse, mutect2, varscan2
- EHMT1 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as rs869312936, COSV58373881; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KNSTRN | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 15/66 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs868438023, COSV51103508; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LZTR1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs869320686, CM154934, COSV53144758; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 60/138 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PCED1B | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 25/171 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs757280610, COSV71394886, COSV71395186; called by muse, mutect2, varscan2
- ACSS3 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs747840747, COSV54089221; called by muse, mutect2, varscan2
- ACTC1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 86/260 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs543030688, CM0910610, COSV51758568; called by muse, mutect2, varscan2
- ADAMTS18 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV51404921; called by muse, mutect2, varscan2
- AFF3 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.182); catalogued as COSV57850894; called by muse, mutect2, varscan2
- AGK | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV62594261; called by muse, mutect2, varscan2
- AHCTF1 | c.3503A>G p.E1168G (on ENST00000366508; = p.E1142G on NM_015446.5) | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs776810110, COSV58248735; called by muse, mutect2, varscan2
- ANXA10 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV63738747; called by muse, mutect2, varscan2
- APOB | c.12760C>T p.P4254S | Missense Mutation (SNP) | VAF 206/583 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.099); catalogued as COSV51932051; called by muse, mutect2, varscan2
- ARHGEF2 | c.2569C>T p.R857* (on ENST00000361247 / NM_001162383.2; = p.R829* on NM_004723.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/48 reads (65%) | catalogued as rs1438448161, COSV58109693; called by muse, mutect2, varscan2
- ARID1B | c.2520C>G p.Y840* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as COSV51658286; called by muse, mutect2, varscan2
- ARMC4 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV53464318; called by muse, mutect2, varscan2
- B3GALT1 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV59908514; called by muse, varscan2
- BATF2 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs757662221, COSV57249793; called by muse, mutect2, varscan2
- BMP8A | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100090219; called by mutect2, varscan2
- C1orf127 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs968010775, COSV65437037; called by muse, mutect2, varscan2
- C1orf94 | c.1030G>A p.E344K (on ENST00000488417 / NM_001134734.2; = p.E154K on NM_032884.5) | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as rs1297961791, COSV64916103; called by muse, mutect2
- CACNA1D | c.4864C>T p.R1622W (on ENST00000350061 / NM_001128840.3; = p.R1642W on NM_000720.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145414503; called by muse, mutect2, varscan2
- CBFA2T2 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV60798331; called by muse, mutect2, varscan2
- CBY2 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs1242283119, COSV60117923, COSV60119400; called by muse, mutect2, varscan2
- CCK | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58183673; called by muse, mutect2, varscan2
- CDH6 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54068101; called by muse, mutect2, varscan2
- CERS4 | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV52166240; called by muse, mutect2, varscan2
- CFH | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 62/94 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV66407570; called by muse, mutect2, varscan2
- CHMP5 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV56302890; called by muse, mutect2, varscan2
- COL21A1 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55159741; called by muse, mutect2, varscan2
- COL4A4 | c.3175C>G p.P1059A | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV61631304; called by muse, mutect2, varscan2
- COL4A4 | c.1298G>A p.G433E | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1468186854, COSV61631309; called by muse, mutect2, varscan2
- COL6A6 | c.1935G>A p.M645I | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.191); catalogued as COSV62019898; called by muse, mutect2, varscan2
- CSN3 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.875); catalogued as rs746268983, COSV100515408, COSV59243925; called by muse, mutect2, varscan2
- CTAGE1 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as rs1181502329, COSV66943311; called by muse, mutect2, varscan2
- CTNNA2 | c.2362C>A p.Q788K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58146912; called by muse, mutect2, varscan2
- CYP19A1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53058646; called by muse, mutect2, varscan2
- DCDC1 | c.2127G>A p.M709I | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.077); catalogued as COSV60839976; called by muse, mutect2
- DDX60 | c.2129C>T p.S710F | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV67096104, COSV67096363; called by muse, mutect2, varscan2
- DLC1 | c.1778C>T p.S593F (on ENST00000276297 / NM_001348081.2; = p.S156F on NM_006094.5) | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52299809; called by muse, mutect2, varscan2
- DMD | c.10168C>T p.P3390S | Missense Mutation (SNP) | VAF 59/80 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58905100; called by muse, mutect2, varscan2
- DMRTA1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV57924132; called by muse, mutect2, varscan2
- DNAH5 | c.11212G>A p.E3738K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54205533, COSV99455398; called by muse, mutect2, varscan2
- ECT2 | c.123T>A p.Y41* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV51688056; called by muse, mutect2, varscan2
- ERMARD | c.1465C>T p.H489Y | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as COSV64647937; called by muse, mutect2, varscan2
- ETV6 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 71/121 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs762232508, COSV67148843; called by muse, mutect2, varscan2
- EZHIP | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.662); catalogued as COSV100539875; called by muse, mutect2, varscan2
- EZHIP | c.1211T>A p.V404D | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100539876; called by muse, mutect2, varscan2
- FGF23 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); catalogued as COSV52975700; called by muse, mutect2, varscan2
- GPC5 | c.490A>G p.N164D | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as COSV65592039; called by muse, mutect2, varscan2
- GRHPR | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV58942464; called by muse, mutect2, varscan2
- GRM3 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.292); catalogued as COSV64470358; called by muse, mutect2, varscan2
- HELQ | c.347A>G p.E116G | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.03); catalogued as COSV55024873; called by muse, mutect2, varscan2
- HGF | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55948020; called by muse, mutect2, varscan2
- HMGXB4 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as COSV53333620; called by muse, mutect2, varscan2
- IDO1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53713747; called by muse, mutect2, varscan2
- IL10RB | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as rs1321425844, COSV51614050; called by muse, mutect2, varscan2
- IQCF1 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV58823333; called by muse, mutect2, varscan2
- KCNG1 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs1315910597, COSV65368839; called by muse, mutect2
- KIF2A | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV66945321; called by muse, mutect2, varscan2
- KIR3DL1 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs761972118; called by muse, mutect2
- LARGE2 | c.1759C>T p.H587Y | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV57652659; called by muse, mutect2, varscan2
- LRP1B | c.9293G>A p.G3098E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV67194231; called by muse, mutect2, varscan2
- MAGEE2 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777715056, COSV64897574; called by muse, mutect2, varscan2
- MAP4K3 | c.1359T>G p.D453E | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.022); catalogued as COSV55712077; called by muse, mutect2, varscan2
- MTG2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63693667; called by muse, mutect2, varscan2
- MUC16 | c.12032C>T p.S4011F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV67460203; called by muse, mutect2, varscan2
- MYH4 | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55116538; called by muse, mutect2, varscan2
- MYH4 | c.4352G>A p.R1451K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV104370722, COSV55114667; called by muse, mutect2, varscan2
- MYO9A | c.3538G>A p.G1180R | Missense Mutation (SNP) | VAF 83/211 reads (39%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV61849824; called by muse, mutect2, varscan2
- NAA60 | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.22); catalogued as COSV62654614; called by muse, mutect2, varscan2
- NADK2 | c.560+1G>A p.X187_splice (on ENST00000381937 / NM_001085411.3; = p.X24_splice on NM_153013.4) | Splice Site (SNP) | VAF 17/61 reads (28%) | catalogued as COSV56936021; called by muse, mutect2, varscan2
- NLRC3 | c.1237T>G p.Y413D | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV57089770; called by muse, mutect2, varscan2
- NLRP11 | c.926T>G p.F309C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV64086766; called by muse, mutect2, varscan2
- OR1J4 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV61589744; called by muse, mutect2, varscan2
- OR2G2 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.876); catalogued as COSV60739860; called by muse, mutect2
- OR5I1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV56886456; called by muse, mutect2, varscan2
- OR5P2 | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV61490143; called by muse, mutect2, varscan2
- P3H1 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.036); catalogued as COSV99355507; called by muse, mutect2, varscan2
- PCDHA2 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.865); catalogued as COSV65366013; called by muse, mutect2, varscan2
- PCDHB9 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs782255448, COSV53377824; called by muse, mutect2, varscan2
- PDZD2 | c.3275G>A p.R1092H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs755711661, COSV56856241; called by muse, mutect2, varscan2
- PKD1L2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs748102348, COSV61414240; called by muse, mutect2, varscan2
- PKHD1L1 | c.9352G>A p.E3118K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV65740210; called by muse, mutect2, varscan2
- PLK1 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55621182; called by muse, mutect2
- PPP6R3 | c.1293T>A p.C431* (on ENST00000393800 / NM_001352375.2; = p.C380* on NM_018312.5) | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV55725010; called by muse, mutect2
- PRUNE2 | c.6583A>G p.I2195V | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV65040585; called by muse, mutect2, varscan2
- PWWP3B | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV100531223, COSV61799274; called by muse, mutect2, varscan2
- RALGDS | c.2476C>T p.P826S | Missense Mutation (SNP) | VAF 101/227 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV64426709; called by muse, mutect2, varscan2
- RASGRF2 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54127851; called by muse, mutect2, varscan2
- SCEL | c.1331A>G p.N444S (on ENST00000349847 / NM_144777.3; = p.N424S on NM_003843.4) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as COSV62993309; called by muse, mutect2, varscan2
- SCN10A | c.4483G>A p.V1495M | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV71861003; called by muse, mutect2, varscan2
- SCN10A | c.1953G>A p.W651* | Nonsense Mutation (SNP) | VAF 42/122 reads (34%) | catalogued as COSV71861005; called by muse, mutect2, varscan2
- SCN11A | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs146174311, CM145676, COSV56568803; called by muse, mutect2, varscan2
- SEMA3E | c.2313C>A p.H771Q | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV57086747; called by muse, mutect2, varscan2
- SETDB1 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 48/83 reads (58%) | catalogued as COSV54980832; called by muse, mutect2, varscan2
- SLC12A8 | c.1584G>A p.W528* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as COSV58865321; called by muse, mutect2, varscan2
- SLCO4A1 | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.029); catalogued as rs185048623, COSV53890340; called by muse, mutect2, varscan2
- SLCO4A1 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV53890360; called by muse, varscan2
- SORBS1 | c.2551C>T p.P851S (on ENST00000361941 / NM_001034954.2; = p.P501S on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV53356188; called by muse, mutect2, varscan2
- SYCE1 | c.856G>A p.G286R (on ENST00000343131 / NM_001143764.3; = p.G250R on NM_130784.3) | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.918); catalogued as COSV58216791; called by muse, mutect2, varscan2
- TAF1L | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV54260687; called by muse, varscan2
- TANGO6 | c.2350C>T p.H784Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55763947; called by muse, mutect2, varscan2
- TAT | c.872G>A p.W291* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV63532638; called by muse, mutect2, varscan2
- TBX10 | c.483G>A p.W161* | Nonsense Mutation (SNP) | VAF 34/237 reads (14%) | catalogued as COSV56875444; called by muse, mutect2, varscan2
- TCL1A | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.213); catalogued as COSV68085421; called by muse, mutect2, varscan2
- TEK | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.744); catalogued as COSV66228594; called by muse, mutect2, varscan2
- TEKT5 | c.1250A>C p.N417T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV51588059; called by muse, mutect2
- TENM2 | c.6736T>A p.L2246M (on ENST00000518659 / NM_001122679.2; = p.L2007M on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69127959; called by muse, mutect2, varscan2
- THSD1 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs141269153, COSV51627897; called by muse, mutect2, varscan2
- THSD7B | c.3067C>T p.R1023* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as rs750153977, COSV55661886; called by muse, mutect2, varscan2
- TOP2A | c.2902T>C p.F968L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV70732410; called by muse, mutect2, varscan2
- TP53BP1 | c.4396C>T p.P1466S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs267604218, COSV55499595; called by muse, mutect2, varscan2
- TRMT10A | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200935064, COSV56744811; called by muse, mutect2, varscan2
- TUBA3D | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV58311405; called by muse, mutect2, varscan2
- UGT2A2 | c.341G>A p.W114* | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | catalogued as COSV54140366; called by muse, mutect2, varscan2
- UIMC1 | c.521A>T p.N174I | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV65893430; called by muse, mutect2, varscan2
- UNC13A | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV53193229; called by muse, mutect2, varscan2
- USH1G | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV58881532; called by muse, mutect2, varscan2
- USHBP1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as COSV53103125; called by muse, mutect2, varscan2
- VIT | c.230A>T p.D77V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as COSV64896034, COSV64896244; called by muse, mutect2, varscan2
- VPS54 | c.191G>A p.W64* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as COSV55440046; called by muse, mutect2, varscan2
- VWA2 | c.721C>G p.P241A | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV53906090; called by muse, mutect2, varscan2
- WDR31 | c.634C>T p.L212F (on ENST00000374193 / NM_001006615.3; = p.L211F on NM_145241.5) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV59145853; called by muse, mutect2, varscan2
- WDR59 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); catalogued as rs569472427, COSV50934760; called by muse, mutect2, varscan2
- WDR72 | c.1802G>A p.R601Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs368755797; called by muse, mutect2, varscan2
- XRN1 | c.4766C>T p.P1589L | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1275939654, COSV53810498; called by muse, mutect2, varscan2
- ZFHX4 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 93/206 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs373874710, COSV51483834; called by muse, mutect2, varscan2
- ZFP42 | c.261A>T p.E87D | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV58817108; called by muse, mutect2, varscan2
- ZFX | c.2261A>G p.Y754C | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58447174; called by muse, mutect2, varscan2
- ZNF407 | c.3733C>T p.P1245S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV55249717; called by muse, mutect2, varscan2
- ZNF536 | c.3610G>A p.D1204N | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); catalogued as rs753985257, COSV62822017, COSV62822575; called by muse, mutect2, varscan2
- PRRC2B | c.2518_2519dup p.G841Qfs*108 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- ADGRF4 | c.1731T>A p.V577= | Silent (SNP) | VAF 126/209 reads (60%) | catalogued as COSV51951599; called by muse, mutect2, varscan2
- ADRB2 | c.909C>T p.I303= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV60005385; called by muse, mutect2, varscan2
- APOBEC3B | c.144C>T p.L48= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV59840686; called by muse, mutect2, varscan2
- BLMH | c.480C>T p.I160= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV55585158; called by muse, mutect2, varscan2
- CAMKV | c.159G>A p.K53= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV56555007; called by muse, mutect2, varscan2
- CD33 | c.441C>T p.I147= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV51799946; called by muse, mutect2, varscan2
- CDH6 | c.2034G>A p.R678= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV54065228, COSV54072245; called by muse, mutect2, varscan2
- CLN6 | c.798C>T p.F266= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as rs140319056; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- COX10 | c.324T>A p.S108= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV55404404; called by muse, mutect2, varscan2
- CYP2C9 | c.1026G>A p.R342= | Silent (SNP) | VAF 45/128 reads (35%) | catalogued as rs56718285, COSV53247969; called by muse, mutect2, varscan2
- DLL3 | c.1776C>T p.F592= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs773012836, COSV52693372; called by muse, mutect2, varscan2
- FBXO5 | c.507C>T p.F169= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs778911944, COSV57670509; called by muse, mutect2, varscan2
- INPP5B | c.2658G>A p.L886= (on ENST00000373023; = p.L806= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV65960424; called by muse, mutect2, varscan2
- JMJD1C | c.564C>G p.S188= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV101232443, COSV101232472, COSV67860694; called by muse, mutect2, varscan2
- KIRREL2 | c.870C>T p.S290= | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as COSV52875716; called by muse, mutect2, varscan2
- LRRK2 | c.7335A>T p.I2445= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV54150183; called by muse, mutect2, varscan2
- MRPL9 | c.579C>T p.F193= | Silent (SNP) | VAF 68/101 reads (67%) | catalogued as rs866644572, COSV58617965, COSV58619771; called by muse, mutect2, varscan2
- MTNR1A | c.705G>A p.R235= | Silent (SNP) | VAF 41/151 reads (27%) | catalogued as COSV56155639, COSV56156629; called by muse, mutect2, varscan2
- MUC5B | c.7296G>A p.T2432= | Silent (SNP) | VAF 49/176 reads (28%) | catalogued as rs1293066368, COSV71591393; called by muse, mutect2, varscan2
- NCKAP1L | c.261C>T p.F87= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV53205780, COSV99514452; called by muse, mutect2, varscan2
- NPC1L1 | c.1482C>T p.F494= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV56924253; called by muse, mutect2, varscan2
- NUMA1 | c.4881G>A p.Q1627= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV59643215; called by muse, mutect2, varscan2
- OR13F1 | c.942C>T p.F314= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV58251342, COSV58252573; called by muse, mutect2, varscan2
- OR1C1 | c.519C>T p.I173= | Silent (SNP) | VAF 42/67 reads (63%) | catalogued as rs370826315, COSV68715504; called by muse, mutect2, varscan2
- OR2T3 | c.594C>T p.S198= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as COSV100612983, COSV62082222; called by muse, mutect2, varscan2
- OR4C12 | c.330C>T p.I110= | Silent (SNP) | VAF 50/164 reads (30%) | catalogued as COSV58859529; called by muse, mutect2, varscan2
- OR6K3 | c.507C>T p.F169= (on ENST00000368146; = p.F153= on NM_001005327.2) | Silent (SNP) | VAF 96/140 reads (69%) | catalogued as COSV63745527; called by muse, mutect2, varscan2
- PCDHA6 | c.144C>T p.I48= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV65351355; called by muse, mutect2, varscan2
- PGS1 | c.609G>A p.L203= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as rs1212900100, COSV53144669; called by muse, mutect2, varscan2
- PLEKHG7 | c.472C>T p.L158= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV67337811; called by muse, mutect2
- PNPLA7 | c.1983C>T p.A661= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as rs757572092, COSV52997608, COSV99481225; called by muse, mutect2, varscan2
- RASSF9 | c.90G>A p.V30= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV63433253; called by muse, mutect2, varscan2
- RIN2 | c.1128G>A p.R376= (on ENST00000255006 / NM_001242581.1; = p.R327= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV54786881; called by muse, mutect2, varscan2
- RNF150 | c.339C>T p.R113= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1416286569, COSV60789639; called by muse, mutect2, varscan2
- RNF151 | c.219G>A p.R73= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV58399687; called by muse, mutect2, varscan2
- RSAD1 | c.573C>T p.R191= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs1555615154, COSV51955344; called by muse, mutect2, varscan2
- RTEL1 | c.636C>T p.S212= | Silent (SNP) | VAF 68/589 reads (12%) | catalogued as COSV58892824; called by muse, mutect2, varscan2
- S100A7L2 | c.305G>A p.*102= | Silent (SNP) | VAF 57/488 reads (12%) | catalogued as COSV64194987; called by muse, mutect2, varscan2
- SALL3 | c.252G>A p.E84= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV73305962; called by muse, mutect2, varscan2
- SCN5A | c.423C>T p.I141= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1381613896, COSV61121538; called by muse, mutect2, varscan2
- SDR16C5 | c.228G>A p.G76= | Silent (SNP) | VAF 90/123 reads (73%) | catalogued as COSV58126162; called by muse, mutect2, varscan2
- SLC13A3 | c.825C>T p.F275= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs767379024, COSV51714608; called by muse, mutect2, varscan2
- SLC34A1 | c.987A>T p.G329= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV60996440; called by muse, mutect2, varscan2
- SLC45A3 | c.757C>T p.L253= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV65654834; called by muse, mutect2, varscan2
- SLCO4A1 | c.1662C>A p.I554= | Silent (SNP) | VAF 28/162 reads (17%) | catalogued as COSV53890349; called by muse, varscan2
- SSH1 | c.1818C>T p.T606= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV58455835; called by muse, mutect2, varscan2
- SZT2 | c.3915C>T p.V1305= (on ENST00000634258 / NM_001365999.1; = p.V1248= on NM_015284.4) | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV65169122; called by muse, mutect2, varscan2
- THSD7B | c.1536G>A p.T512= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs867645142, COSV55676104; called by muse, mutect2, varscan2
- TLE2 | c.942C>T p.T314= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs1367079752, COSV53579508; called by muse, mutect2, varscan2
- TMCO4 | c.153C>T p.S51= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV53871810; called by muse, mutect2, varscan2
- TTN | c.72411G>A p.G24137= (on ENST00000591111; = p.G16713= on NM_003319.4) | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs756671220, COSV59995079; called by muse, mutect2, varscan2
- TTN | c.59283C>T p.I19761= (on ENST00000591111; = p.I12337= on NM_003319.4) | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as rs752270069, COSV59995114; ClinVar: likely benign; called by muse, mutect2, varscan2
- XRCC3 | c.186C>T p.I62= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV61398694; called by muse, mutect2, varscan2
- ZFHX3 | c.5751G>A p.E1917= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as rs772844151, COSV51715433; called by muse, mutect2, varscan2
- ZFHX4 | c.1995G>A p.E665= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV50684672, COSV99262222; called by muse, mutect2, varscan2
- ZNF18 | c.252C>T p.L84= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV59551103; called by muse, mutect2, varscan2
- ZNF407 | c.3021C>T p.S1007= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as rs372408214, COSV55249684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65501110 T>C | 5'Flank (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- MIR518C | n.25C>T | RNA (SNP) | VAF 12/30 reads (40%) | catalogued as rs1170322752; called by muse, mutect2, varscan2
- NBPF25P | n.1993G>A | RNA (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- OBSCN | c.5138-1607C>T | Intron (SNP) | VAF 36/69 reads (52%) | catalogued as rs752414648, COSV99483218; called by muse, mutect2, varscan2
- OR1N2 | c.-12G>A | 5'UTR (SNP) | VAF 26/59 reads (44%) | catalogued as rs758461490, COSV65460499; called by muse, mutect2, varscan2
- SNORD113-4 | n.65C>T | RNA (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- TTN | c.10360+3294A>C | Intron (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100626559, COSV60314965; called by muse, mutect2, varscan2
- VAX1 | chr10:117132237 G>A | 3'Flank (SNP) | VAF 35/111 reads (32%) | catalogued as COSV53328674, COSV53329131; called by muse, mutect2, varscan2
